MMRF case MMRF_2572 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/3ef52c42-d0cf-4c42-8a76-e7e3b777fccf

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.7 years (27,642 days); ISS stage: II; Days to last known disease status: 630 days (1.7 years); Days to last follow up: 630 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 3): M Protein 2.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 5.68 g/L; Immunoglobulin A 20.7 g/L; Immunoglobulin M 0.426 g/L; Beta 2 Microglobulin 5.24 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.15 ×10⁹/L; Absolute Neutrophil 4.28 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.33 mmol/L; Albumin 29 g/L; Total Protein 7.1 g/dL; Glucose 5.61 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 96 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 6.59 g/L; Immunoglobulin A 0.934 g/L; Immunoglobulin M 0.323 g/L; Beta 2 Microglobulin 7.46 µg/mL; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.93 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 192 µmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.12 mmol/L.
- Day 176: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 0.559 g/L; Immunoglobulin M 0.236 g/L; Beta 2 Microglobulin 3.68 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 2.28 ×10⁹/L; Absolute Neutrophil 1.47 ×10⁹/L; Platelets 86 ×10⁹/L; Creatinine 144 µmol/L; Calcium 2.1 mmol/L; Albumin 40 g/L; Total Protein 5.8 g/dL; Glucose 4.46 mmol/L.
- Day 256: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 5.87 g/L; Immunoglobulin A 0.637 g/L; Immunoglobulin M 0.168 g/L; Beta 2 Microglobulin 5.27 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 3.22 ×10⁹/L; Absolute Neutrophil 2.43 ×10⁹/L; Platelets 74 ×10⁹/L; Creatinine 170 µmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 5.28 mmol/L.
- Day 348 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 0.647 g/L; Immunoglobulin M 0.222 g/L; Beta 2 Microglobulin 5.26 µg/mL; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 60 ×10⁹/L; Creatinine 169 µmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 4.79 mmol/L.
- Day 425 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 7.46 g/L; Immunoglobulin A 0.849 g/L; Immunoglobulin M 0.231 g/L; Beta 2 Microglobulin 5.62 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 4.96 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 205 µmol/L; Calcium 2.18 mmol/L; Albumin 41.6 g/L; Total Protein 6.2 g/dL; Glucose 4.9 mmol/L.
- Day 532: M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.47 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.96 g/L; Beta 2 Microglobulin 5.2 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 69 ×10⁹/L; Creatinine 165 µmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 5.67 mmol/L.
- Day 630: M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.71 mg/dL; Immunoglobulin G 14.3 g/L; Immunoglobulin A 3.52 g/L; Immunoglobulin M 0.622 g/L; Beta 2 Microglobulin 6.22 µg/mL; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 3.51 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 128 µmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.22 mmol/L.

Other clinical attributes
- Day -1: Weight: 71 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_2572_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2572_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
